Somatic mutation profile of tumor specimen TARGET-40-PANPUM-01A (aliquot TARGET-40-PANPUM-01A-01D) from TARGET case TARGET-40-PANPUM, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Age at diagnosis: 16.4 years (5,996 days).
Specimen TARGET-40-PANPUM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 490372ad-5f29-48c7-8f71-f31c3ac51525.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PANPUM-10A (Blood Derived Normal), aliquot TARGET-40-PANPUM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b043db9-79ce-489c-8452-89786f97e075

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 7, Intron 3, Splice Site 3, 3'UTR 2, 5'UTR 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADA2 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as rs369306297; called by muse, mutect2, varscan2
- ADGRA2 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV55103388; called by muse, mutect2, varscan2
- ALS2CL | c.2685-2A>G p.X895_splice | Splice Site (SNP) | VAF 31/96 reads (32%) | catalogued as rs111301122; called by muse, mutect2, varscan2
- AXDND1 | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs202143471, COSV100858281; called by muse, mutect2, varscan2
- DNAH9 | c.3677G>A p.R1226K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764552694; called by muse, mutect2, varscan2
- DTNA | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs954418044, COSV51998737; called by muse, mutect2, varscan2
- GRM3 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64481695; called by muse, mutect2
- H3C4 | c.34A>G p.T12A | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV61912158; called by muse, mutect2
- KRT76 | c.1364A>G p.Q455R | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs992355167; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57929942; called by muse, mutect2, varscan2
- RYR1 | c.12406C>T p.R4136C | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as CM023977, COSV62094616; called by muse, mutect2, varscan2
- SLC35A1 | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs757048979; called by muse, mutect2, varscan2
- SPTBN5 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1393495637; called by muse, mutect2, varscan2
- TMEM132D | c.2716C>T p.L906F | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs753570003; called by muse, mutect2, varscan2
- ABCC8 | c.1672-1G>A p.X558_splice | Splice Site (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2
- ADGRA2 | c.2888G>A p.S963N | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- DAAM2 | c.2253-40_2259del p.X751_splice | Splice Site (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- DENND1C | c.893C>G p.T298S | Missense Mutation (SNP) | VAF 69/479 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GBF1 | c.3278G>C p.S1093T (on ENST00000369983 / NM_001377137.1; = p.S1092T on NM_004193.3) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- GRM7 | c.2362A>C p.K788Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HRCT1 | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.549); called by muse, mutect2
- LRRC3B | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- LRRC43 | c.1445A>C p.K482T | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP7 | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 85/406 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- NR2F6 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OTOGL | c.1265A>T p.D422V (on ENST00000547103; = p.D413V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCK2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 86/386 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by mutect2, varscan2
- TDRD1 | c.1613C>G p.S538C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.3044G>T p.C1015F (on ENST00000591111; = p.C969F on NM_003319.4) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP11 | c.2383G>T p.E795* (on ENST00000218348; = p.E752* on NM_001371072.1) | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- ZNF318 | c.6542G>A p.G2181E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- ADAMTS10 | c.2631C>T p.R877= | Silent (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- BEND2 | c.1596A>G p.Q532= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs997676259; called by muse, mutect2, varscan2
- GREM2 | c.48G>A p.V16= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV58956435; called by muse, mutect2
- NPTXR | c.924C>T p.R308= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs193224451, COSV60728914; called by muse, mutect2, varscan2
- RELL1 | c.192C>T p.V64= | Silent (SNP) | VAF 85/323 reads (26%) | called by muse, mutect2, varscan2
- VAV1 | c.270G>C p.R90= | Silent (SNP) | VAF 828/1140 reads (73%) | catalogued as COSV58380044; called by muse, varscan2
- WNT7B | c.522G>A p.K174= | Silent (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- CALCA | c.*4C>G | 3'UTR (SNP) | VAF 51/228 reads (22%) | called by muse, mutect2, varscan2
- CYP4F3 | c.*113C>T | 3'UTR (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- HPN-AS1 | n.132C>G | RNA (SNP) | VAF 66/317 reads (21%) | called by muse, mutect2, varscan2
- ITGB8 | c.801+65T>C | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- KPNA6 | c.-65C>G | 5'UTR (SNP) | VAF 8/148 reads (5%) | catalogued as rs1474630928; called by muse, mutect2
- MAP3K14 | c.1821+80C>T | Intron (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- PHTF1 | c.-30-66C>T | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
